Somatic mutation profile of tumor specimen 0DSEZI from CCDI case PBCGJN, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Adrenal cortical carcinoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 7.8 years (2,831 days).
Specimen 0DSEZI: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0372629-3f8a-4644-8d5b-201240dd598e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSEYS (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/610a6504-f2a8-447d-9914-7a244181b1dc

The open-access MAF lists 22 somatic variants for this specimen: 14 protein-altering or splice-affecting, 5 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 5, Intron 2, Frame Shift Ins 1, 3'UTR 1, Nonsense Mutation 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- A3GALT2 | c.643G>A p.E215K | Missense Mutation (SNP) | VAF 108/303 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.771); catalogued as rs1222799632, COSV57760281; called by muse, mutect2, varscan2
- CSGALNACT1 | c.1345G>C p.E449Q | Missense Mutation (SNP) | VAF 303/1032 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs544410186; called by muse, mutect2, varscan2
- CTNNB1 | c.274C>G p.Q92E | Missense Mutation (SNP) | VAF 456/1027 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.094); catalogued as COSV62713130; called by muse, mutect2, varscan2
- KRT17 | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 177/484 reads (37%) | SIFT tolerated (0.13); PolyPhen benign (0.11); catalogued as rs775474574; called by muse, mutect2, varscan2
- LRRIQ1 | c.3752C>G p.S1251C | Missense Mutation (SNP) | VAF 94/2618 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.533); catalogued as rs1325780232, COSV67839663; called by muse, mutect2
- NR1I2 | c.1057C>T p.R353C | Missense Mutation (SNP) | VAF 141/612 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747428529; called by muse, mutect2, varscan2
- AQP1 | c.668C>T p.A223V | Missense Mutation (SNP) | VAF 212/1039 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ELOA2 | c.762C>A p.C254* | Nonsense Mutation (SNP) | VAF 216/667 reads (32%) | called by muse, mutect2, varscan2
- MED13L | c.289G>C p.V97L | Missense Mutation (SNP) | VAF 241/1388 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- MUC4 | c.15274A>G p.K5092E (on ENST00000463781 / NM_018406.7; = p.K856E on NM_004532.6) | Missense Mutation (SNP) | VAF 261/996 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SERGEF | c.1169G>A p.G390D | Missense Mutation (SNP) | VAF 344/1038 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SYNE2 | c.8220C>G p.I2740M | Missense Mutation (SNP) | VAF 256/1098 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TCF4 | c.208-2A>G p.X70_splice | Splice Site (SNP) | VAF 138/490 reads (28%) | called by muse, mutect2, varscan2
- UBA3 | c.504dup p.I169Yfs*18 | Frame Shift Ins (INS) | VAF 249/1327 reads (19%) | called by mutect2, pindel, varscan2
- ANPEP | c.1362G>A p.P454= | Silent (SNP) | VAF 250/890 reads (28%) | catalogued as rs747845929, COSV55589940; called by muse, mutect2, varscan2
- PRLHR | c.852G>A p.V284= | Silent (SNP) | VAF 156/558 reads (28%) | called by muse, mutect2, varscan2
- SLC25A32 | c.642C>T p.I214= | Silent (SNP) | VAF 226/780 reads (29%) | called by muse, mutect2, varscan2
- SLC6A3 | c.666G>T p.L222= | Silent (SNP) | VAF 220/901 reads (24%) | catalogued as COSV99548078; called by muse, mutect2, varscan2
- USF3 | c.4611C>T p.S1537= | Silent (SNP) | VAF 578/1169 reads (49%) | called by muse, mutect2, varscan2
- GSDME | c.*2G>T | 3'UTR (SNP) | VAF 227/1054 reads (22%) | called by muse, mutect2, varscan2
- MMP26 | c.-145+93127G>C | Intron (SNP) | VAF 260/1662 reads (16%) | called by muse, mutect2, varscan2
- MUCL3 | c.947-657C>G | Intron (SNP) | VAF 223/993 reads (22%) | called by muse, mutect2, varscan2
